Surgical pathology report (de-identified scan), TCGA case TCGA-CE-A27D, project TCGA-THCA (Thyroid Carcinoma), tissue source site ILSBio, specimen TCGA-CE-A27D-01A (Primary Tumor).

[page 1 of 6]
100-0-3
Carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS 873.9

IRB APPROVED

Form Revised

Clinical Case Report (For Collection of Cancerous Tissue)

Informed Consent

Noted		
Reviewed/Initials	Date Reviewed: 5/10/11	

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	6'0"	☐ Single ☒ Married		
☐ Male ☒ Female	Weight	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
	52 kg		11/7	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Difficult to swallow; vocal changed 2 months ago.
Symptoms: weight loss.
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☒ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 6]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY			
Menopausal Status ☒ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses		# of Pregnancies
	years old		01
	Date of Last Menses		# of Live Births
Birth Control: ☐ Condom ☒ Oral Contraceptive ☐ IUD ☐ Other:			☐ Hormone Replacement Therapy:

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA					
Test	Result	Date	Test	Result	Date
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____	
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	
B/T Cell Markers:					

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy X	Thyroid Cancer	

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T 2 N 1 M 0 Stage: I		

Treatment Information

SURGICAL TREATMENT		
Procedure		Date of Procedure
Thyroidectomy		
Primary Tumor		
Organ	Detailed Location	Size
Thyroid tumor		3 x 2 x 1.5 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T 2 N 1 M 0 Stage: I		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

Collected by: 114 Date: 11/11/11 Time: 1:15

Preserved by: 114 Date: 11/11/11 Time: 1:15

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	0	4	0			4	0
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Thyroid tumor	3.5 x 2 x 1.5 cm		cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 2 N 1 M 0		Stage: I	
Notes: Thyroid nodes (M1, M2 = positive) (Total: 8 nodes: " 8 nodes = positive)			

[page 5 of 6]
Microscopic Description

Histological Pattern											
Cell Distribution					Structural Pattern						
	+	-							+	-	
Diffuse		☒			Streaming						
Mosaic					Storiform						
Necrosis					Fibrosis						
Lymphocytic Infiltration		☒			Palisading						
Vascular Invasion					Cystic Degeneration						
Clusterized					Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						

Cellular Differentiation											
Squamous			Adenomatous			Sarcomatous			Lymphomatous		
	+	-		+	-		+	-		+	-
Squamoid Cell			Glandular cell		☒	Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		

Cellular Differentiation:	Well	Moderate ☒	Poor
---------------------------	------	--	------

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		☒		
Hyperchromatism			☒	
Nucleolar Prominent			☒	
Multinucleated Giant Cell			☒	
Mitotic Activity		☒		

Nuclear Grade:			
----------------	--	--	--

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: papillary carcinoma of the thyroid
(moderately differentiated)

Grade: II

Comments:

Principal Investigator

Pathologist

Date

[page 6 of 6]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse			☒	Streaming			
Mosaic		☒		Storiform			
Necrosis			☒	Fibrosis			
Lymphocytic Infiltration		☒		Palisading			
Vascular Invasion			☒	Cystic Degeneration			
Clusterized			☒	Bleeding			
Alveolar Formation			☒	Myxoid Change			
Indian File			☒	Psammoma/Calcification			

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamous Cell			Glandular cell	☒		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	☒		Fibroblast			Small Cell		
Keratin			Secretion	☒		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	☒		Lipoblast			Inflam. Cell		
Pearl			Gland formation		☒	Myoblast			Plasma Cell		
Otherwise Specified: D1 507r D2 607r D3 07r D4 07r											

2. Cellular Differentiation:

Well	Moderately	Poor
☒		

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis		☒		
Hyperchromatism		☒		
Nucleolar Prominent		☒		
Multinucleated Giant Cell		☒		
Mitotic Activity		☒		
Nuclear Grade				

Histological Diagnosis: Papillary Thyroid Carcinoma, G-1

Comments: M, N₂: Carcinoma metastasized to LN.

Date

Director, Research Pathology

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

Source: NCI Genomic Data Commons file 07e0649a-a4f3-4082-8b4a-4c87d41111e6 (TCGA-CE-A27D.5261BBFC-934D-4929-BB25-1C5A49DAFB00.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).